Somatic mutation profile of tumor specimen ALCH-B263-TTP1-A (aliquot ALCH-B263-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B263, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.6 years (18,484 days).
Specimen ALCH-B263-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deb7a5a2-e167-4084-bf95-5e49e2c04add.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B263-NB1-A (Blood Derived Normal), aliquot ALCH-B263-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7222daf5-51e8-4de0-8e60-add243cc10bd

The open-access MAF lists 52 somatic variants for this specimen: 29 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 15, Intron 4, 5'UTR 3, Splice Region 2, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 40/240 reads (17%) | catalogued as rs876659384, COSV52700095, COSV52863161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANTXRL | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 23/343 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as rs1554958624; called by muse, mutect2
- BMP1 | c.105G>C p.E35D | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.216); catalogued as COSV59244224; called by muse, mutect2, varscan2
- CAPSL | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 52/378 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs200635899; called by muse, mutect2, varscan2
- CCN4 | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.039); catalogued as rs1317326427; called by muse, mutect2
- COL6A3 | c.5656C>T p.R1886C | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as CM161508, COSV55102043; called by muse, mutect2, varscan2
- DPYSL4 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as rs367953043; called by muse, mutect2
- DPYSL4 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1264770014; called by muse, mutect2, varscan2
- GABRA4 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.015); catalogued as COSV99974768; called by muse, mutect2
- GIMAP8 | c.968G>C p.G323A | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV56231297; called by muse, mutect2
- L3MBTL3 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV62384040; called by muse, mutect2
- MAGEB17 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs768625586; called by muse, mutect2
- MIEN1 | c.264+3_264+6del | Splice Region (DEL) | VAF 38/201 reads (19%) | catalogued as rs757438769; called by pindel, varscan2
- NCL | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 38/570 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.984); catalogued as COSV59544774; called by muse, mutect2
- OR6X1 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs769223766, COSV60009303; called by muse, mutect2
- PAK5 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1234148699, COSV62024968; called by muse, mutect2
- RYR2 | c.3484G>A p.V1162M | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs377030538; ClinVar: uncertain significance; called by muse, mutect2
- SLC2A12 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs779184200, COSV51597479; called by muse, varscan2
- UTP6 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs909046283; called by muse, mutect2
- IBA57 | c.468del p.E156Dfs*95 | Frame Shift Del (DEL) | VAF 37/265 reads (14%) | called by mutect2, pindel, varscan2
- NCKAP5 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- REEP2 | c.527C>G p.P176R | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- RET | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 103/635 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SETX | c.4862C>T p.S1621L | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- SLC24A2 | c.957A>C p.E319D | Missense Mutation (SNP) | VAF 55/372 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, varscan2
- TRIM65 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- UNC5C | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- XAB2 | c.1119G>A p.E373= | Splice Region (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- ZNF469 | c.7249A>C p.K2417Q (on ENST00000437464; = p.K2445Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- ADCY5 | c.1485C>T p.N495= | Silent (SNP) | VAF 54/286 reads (19%) | catalogued as rs752962640, COSV100568536; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATR | c.3225G>A p.L1075= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV63386334; called by muse, mutect2
- CBX6 | c.693C>T p.A231= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- CPT1A | c.462C>G p.V154= | Silent (SNP) | VAF 43/557 reads (8%) | called by muse, mutect2
- CRB2 | c.3186C>T p.P1062= | Silent (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- LAMB3 | c.1335C>T p.D445= | Silent (SNP) | VAF 38/344 reads (11%) | catalogued as rs374430633; called by muse, mutect2, varscan2
- LPP | c.927C>T p.G309= | Silent (SNP) | VAF 28/319 reads (9%) | catalogued as rs778292002; called by muse, mutect2
- MFHAS1 | c.36G>A p.A12= | Silent (SNP) | VAF 30/325 reads (9%) | called by muse, mutect2
- POGZ | c.678C>T p.T226= | Silent (SNP) | VAF 106/662 reads (16%) | catalogued as rs760525837; called by muse, mutect2, varscan2
- SASS6 | c.642G>T p.L214= | Silent (SNP) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- SIGLEC10 | c.1575C>T p.N525= | Silent (SNP) | VAF 67/720 reads (9%) | catalogued as rs142490331; called by muse, mutect2
- SLC25A15 | c.324G>A p.Q108= | Silent (SNP) | VAF 53/626 reads (8%) | catalogued as rs756644906; called by muse, mutect2
- TMEM79 | c.1026C>T p.Y342= | Silent (SNP) | VAF 16/274 reads (6%) | catalogued as rs1358419681; called by muse, mutect2
- USP4 | c.2307G>A p.Q769= | Silent (SNP) | VAF 26/378 reads (7%) | called by muse, mutect2
- ZNF575 | c.219G>A p.S73= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs1483967759, COSV58564583; called by muse, mutect2
- AC244197.3 | c.-1955C>T | 5'UTR (SNP) | VAF 6/100 reads (6%) | catalogued as rs782776021; called by muse, mutect2
- CACNA1B | c.530+9459C>T | Intron (SNP) | VAF 34/366 reads (9%) | catalogued as rs572588287; called by muse, mutect2
- EFHC1 | c.*1199C>T | 3'UTR (SNP) | VAF 5/45 reads (11%) | catalogued as rs1379737621; called by muse, mutect2, varscan2
- HSPA1B | c.-177T>G | 5'UTR (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100989296; called by muse, mutect2
- LIPC | c.88+4742T>C | Intron (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 21/198 reads (11%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2, varscan2
- TCOF1 | c.1894-43G>A | Intron (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- TTLL3 | c.2126-252G>A | Intron (SNP) | VAF 35/307 reads (11%) | catalogued as rs762718613; called by muse, mutect2, varscan2
